Somatic mutation profile of tumor specimen TCGA-43-7658-01A (aliquot TCGA-43-7658-01A-11D-2122-08) from TCGA case TCGA-43-7658, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 75.9 years (27,734 days).
Specimen TCGA-43-7658-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3ebe60cf-9307-4f9b-8d16-7106ae13ca02.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-43-7658-10A (Blood Derived Normal), aliquot TCGA-43-7658-10A-01D-2122-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c8348d74-6c17-4f68-be3c-38eb7e5cb536

The open-access MAF lists 226 somatic variants for this specimen: 163 protein-altering or splice-affecting, 60 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 142, Silent 60, Nonsense Mutation 9, Frame Shift Del 3, Splice Region 3, Frame Shift Ins 3, RNA 2, Intron 1, Translation Start Site 1, In Frame Del 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NR3C1 | c.1430G>A p.R477H | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs104893913, CM014593, COSV51541690; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.473G>T p.R158L | Missense Mutation (SNP) | VAF 28/37 reads (76%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs587782144, CM102353, CM165595, CM994513, COSV52676395, COSV52678258, COSV52680378, COSV53545833; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA8 | c.1460A>C p.K487T | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.555); catalogued as COSV99286947; called by muse, mutect2, varscan2
- ACTA1 | c.304G>T p.E102* | Nonsense Mutation (SNP) | VAF 40/88 reads (45%) | catalogued as COSV100796799; called by muse, mutect2, varscan2
- ADAM17 | c.970G>T p.D324Y | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs1467381336, COSV100176534, COSV60398410; called by muse, mutect2, varscan2
- AFF2 | c.1834C>T p.H612Y | Missense Mutation (SNP) | VAF 47/163 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.715); catalogued as COSV99666358; called by muse, mutect2, varscan2
- ALPK3 | c.4549G>A p.A1517T | Missense Mutation (SNP) | VAF 7/118 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99362027; called by muse, mutect2
- ANKRD26 | c.1908G>T p.K636N | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.531); catalogued as COSV101063432; called by muse, mutect2, varscan2
- AP3M1 | c.1003G>C p.V335L | Missense Mutation (SNP) | VAF 72/104 reads (69%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV100786773; called by muse, mutect2, varscan2
- APLP1 | c.1842C>A p.S614R (on ENST00000221891 / NM_001024807.3; = p.S613R on NM_005166.4) | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV99697949; called by muse, mutect2, varscan2
- AQP12B | c.124-6C>T | Splice Region (SNP) | VAF 18/31 reads (58%) | catalogued as rs755000716, COSV101315939; called by muse, mutect2, varscan2
- CACNB1 | c.1020C>G p.I340M | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100703586; called by muse, mutect2
- CAPRIN1 | c.1957C>T p.Q653* | Nonsense Mutation (SNP) | VAF 47/99 reads (47%) | catalogued as COSV100404287; called by muse, mutect2, varscan2
- CCDC39 | c.1790A>T p.E597V | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.39); catalogued as COSV99870673; called by muse, mutect2, varscan2
- CDK5RAP2 | c.4160T>C p.V1387A | Missense Mutation (SNP) | VAF 56/177 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100575748; called by muse, mutect2, varscan2
- CDKL5 | c.1546T>A p.Y516N | Missense Mutation (SNP) | VAF 108/254 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.564); catalogued as COSV101184461; called by muse, mutect2, varscan2
- CETN2 | c.245G>C p.G82A | Missense Mutation (SNP) | VAF 19/146 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as COSV100938690, COSV64744164; called by muse, mutect2, varscan2
- CFAP61 | c.3272T>G p.I1091S | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.173); catalogued as COSV99846688; called by muse, mutect2, varscan2
- CFP | c.522C>G p.C174W | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.148); catalogued as COSV99901682; called by muse, mutect2, varscan2
- CHD7 | c.4621G>T p.D1541Y | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV101418461; called by muse, mutect2, varscan2
- COL15A1 | c.12G>A p.R4= | Splice Region (SNP) | VAF 28/55 reads (51%) | catalogued as COSV100897998; called by muse, mutect2, varscan2
- CR1L | c.1662A>G p.I554M | Missense Mutation (SNP) | VAF 2/12 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.257); catalogued as COSV99688051; called by muse, mutect2
- CSRNP2 | c.614C>T p.A205V | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.784); catalogued as COSV57335146, COSV99950412; called by muse, mutect2, varscan2
- CTDP1 | c.1909G>A p.V637M | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs1278372362, COSV99311126; called by muse, mutect2, varscan2
- CTNND1 | c.1275C>G p.H425Q | Missense Mutation (SNP) | VAF 69/137 reads (50%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.815); catalogued as COSV100650294, COSV62384308; called by muse, mutect2, varscan2
- DCUN1D1 | c.710C>T p.P237L | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99490074; called by muse, mutect2
- DGKI | c.3109C>A p.Q1037K | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99937330; called by muse, mutect2, varscan2
- DNAH5 | c.13451G>T p.G4484V | Missense Mutation (SNP) | VAF 24/178 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1386708737, COSV99448360, COSV99454323; called by muse, mutect2, varscan2
- EDEM2 | c.52C>T p.Q18* | Nonsense Mutation (SNP) | VAF 7/50 reads (14%) | catalogued as COSV100993681, COSV100993850; called by muse, mutect2, varscan2
- ERICH1 | c.516A>C p.K172N | Missense Mutation (SNP) | VAF 34/51 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV100033088; called by muse, mutect2, varscan2
- F5 | c.1838G>T p.C613F | Missense Mutation (SNP) | VAF 62/92 reads (67%) | SIFT deleterious (0.02); PolyPhen benign (0.196); catalogued as COSV100889252; called by muse, mutect2, varscan2
- FAM120A | c.2414A>T p.K805M | Missense Mutation (SNP) | VAF 92/292 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99466643; called by muse, mutect2, varscan2
- FAM135A | c.3232C>G p.Q1078E (on ENST00000370479 / NM_001351599.1; = p.Q865E on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.021); catalogued as COSV99526680; called by muse, mutect2, varscan2
- FAM135B | c.220A>G p.I74V | Missense Mutation (SNP) | VAF 26/37 reads (70%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV99358210; called by muse, mutect2, varscan2
- FAM3B | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1424426371, COSV100783778; called by muse, mutect2, varscan2
- FAT3 | c.8377G>C p.D2793H | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99971188; called by muse, mutect2
- FBN3 | c.8228G>A p.R2743H | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs917658642, COSV99495257; called by muse, mutect2, varscan2
- FGD3 | c.1801G>A p.D601N | Missense Mutation (SNP) | VAF 81/140 reads (58%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as COSV100490905; called by muse, mutect2, varscan2
- FGF23 | c.430G>T p.A144S | Missense Mutation (SNP) | VAF 48/143 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.086); catalogued as COSV99426711; called by muse, mutect2, varscan2
- FIP1L1 | c.1244G>T p.G415V | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100184755; called by muse, mutect2, varscan2
- FLG | c.6148C>A p.H2050N | Missense Mutation (SNP) | VAF 1301/2672 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.807); catalogued as COSV64244804; called by muse, mutect2, varscan2
- FMR1 | c.84A>G p.I28M | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as COSV99503811; called by muse, mutect2, varscan2
- FNDC3B | c.1697C>G p.T566R | Missense Mutation (SNP) | VAF 41/253 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.044); catalogued as COSV61038134, COSV61042953; called by muse, mutect2, varscan2
- FOLR3 | c.212G>T p.S71I | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as COSV100281875, COSV61530050; called by muse, mutect2, varscan2
- FREM1 | c.3448G>T p.D1150Y | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as COSV101084881, COSV101085506; called by muse, mutect2, varscan2
- FUBP3 | c.812G>A p.R271K | Missense Mutation (SNP) | VAF 21/135 reads (16%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.862); catalogued as COSV100156328; called by muse, mutect2, varscan2
- GAB3 | c.1517A>T p.Y506F | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.991); catalogued as COSV100850706; called by muse, mutect2, varscan2
- GAS2L3 | c.75C>A p.H25Q | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV57157232, COSV99903175; called by muse, mutect2, varscan2
- GAS2L3 | c.76G>C p.G26R | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs745960580, COSV99903177; called by muse, mutect2, varscan2
- GDNF | c.224T>A p.L75Q | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.896); catalogued as COSV100427567; called by muse, mutect2, varscan2
- GDPD2 | c.17G>T p.G6V | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.221); catalogued as COSV100978711; called by muse, varscan2
- GLRA2 | c.1162G>A p.A388T | Missense Mutation (SNP) | VAF 132/296 reads (45%) | SIFT tolerated (0.36); PolyPhen benign (0.054); catalogued as COSV99491642; called by muse, mutect2, varscan2
- GP2 | c.743dup p.L248Ffs*35 (on ENST00000381362 / NM_001007240.3; = p.L245Ffs*35 on NM_001502.4) | Frame Shift Ins (INS) | VAF 17/70 reads (24%) | catalogued as COSV56896919; called by mutect2, pindel, varscan2
- GRID2 | c.1778C>A p.P593Q | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.967); catalogued as rs1216156586, COSV99947003; called by muse, mutect2, varscan2
- GRIN2B | c.2573C>A p.P858H | Missense Mutation (SNP) | VAF 44/87 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101663193; called by muse, mutect2, varscan2
- GRXCR1 | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 154/329 reads (47%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.821); catalogued as COSV67674482; called by muse, mutect2, varscan2
- HEMGN | c.389A>T p.E130V | Missense Mutation (SNP) | VAF 69/130 reads (53%) | SIFT tolerated (0.08); PolyPhen benign (0.111); catalogued as COSV52325149, COSV99412523; called by muse, mutect2, varscan2
- HMCN1 | c.7769A>G p.N2590S | Missense Mutation (SNP) | VAF 17/228 reads (7%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as COSV99635974; called by muse, mutect2
- IAPP | c.151C>A p.H51N | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs369714240, COSV99557193, COSV99557221; called by muse, mutect2, varscan2
- IBSP | c.588C>A p.D196E | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.52); PolyPhen benign (0.047); catalogued as rs371985463, COSV99883814; called by muse, mutect2, varscan2
- IBTK | c.1139A>G p.K380R | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.183); catalogued as COSV100091528; called by muse, mutect2, varscan2
- IGSF9B | c.1299G>C p.E433D | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.07); PolyPhen benign (0.442); catalogued as COSV100318466; called by muse, mutect2, varscan2
- IZUMO1R | c.202G>C p.V68L | Missense Mutation (SNP) | VAF 42/202 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.055); catalogued as COSV100126934; called by muse, mutect2, varscan2
- JADE3 | c.451C>A p.L151I | Missense Mutation (SNP) | VAF 37/111 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.026); catalogued as COSV99510315; called by muse, mutect2, varscan2
- JKAMP | c.599C>G p.S200C (on ENST00000554271 / NM_001284201.1; = p.S186C on NM_016475.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/9 reads (78%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.639); catalogued as COSV99711771; called by muse, mutect2, varscan2
- KCNC4 | c.1237C>T p.R413W | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.875); catalogued as rs375468070; called by muse, mutect2, varscan2
- KCNMB2 | c.516C>G p.F172L | Missense Mutation (SNP) | VAF 7/115 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as COSV100844039; called by muse, mutect2
- KIAA1549 | c.779A>G p.H260R | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV99652050; called by muse, mutect2, varscan2
- KLF15 | c.544C>T p.L182F | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.109); catalogued as COSV99955381; called by muse, mutect2, varscan2
- KLK2 | c.236A>T p.N79I | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100320058; called by muse, mutect2, varscan2
- LGALS4 | c.775G>T p.E259* | Nonsense Mutation (SNP) | VAF 23/91 reads (25%) | catalogued as COSV100313376, COSV57042987; called by muse, mutect2, varscan2
- LGI1 | c.1208G>T p.S403I | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101004485; called by muse, mutect2, varscan2
- LRP2 | c.10402C>T p.P3468S | Missense Mutation (SNP) | VAF 38/58 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55561652; called by muse, mutect2, varscan2
- LYST | c.6227C>A p.S2076Y | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV101090324; called by muse, mutect2, varscan2
- MAGEC1 | c.2357C>A p.T786N | Missense Mutation (SNP) | VAF 86/333 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.403); catalogued as COSV99596560; called by muse, mutect2, varscan2
- MAGEL2 | c.2506T>A p.W836R | Missense Mutation (SNP) | VAF 41/70 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.161); catalogued as COSV100046220; called by muse, mutect2, varscan2
- MORC1 | c.377G>A p.C126Y | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99227810; called by muse, mutect2, varscan2
- MPHOSPH10 | c.733G>A p.D245N | Missense Mutation (SNP) | VAF 45/124 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.037); catalogued as rs769216149, COSV99731302; called by muse, mutect2, varscan2
- MXRA5 | c.4695G>C p.Q1565H | Missense Mutation (SNP) | VAF 84/161 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV99479352; called by muse, mutect2, varscan2
- MYH1 | c.4157G>T p.R1386L | Missense Mutation (SNP) | VAF 52/74 reads (70%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV99876915; called by muse, mutect2, varscan2
- MYO10 | c.5733G>A p.M1911I | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.125); catalogued as COSV99946317; called by muse, mutect2, varscan2
- MYO7B | c.2884G>T p.E962* | Nonsense Mutation (SNP) | VAF 7/34 reads (21%) | catalogued as COSV101268395; called by muse, mutect2, varscan2
- NIBAN3 | c.2036C>A p.S679Y | Missense Mutation (SNP) | VAF 35/140 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.827); catalogued as COSV99395297; called by muse, mutect2, varscan2
- NPC1L1 | c.2942C>T p.P981L | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as COSV99202563, COSV99213533; called by muse, mutect2, varscan2
- NUP93 | c.1276G>T p.D426Y | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.608); catalogued as rs771500693, COSV100360517; called by muse, mutect2, varscan2
- NXF1 | c.262G>A p.D88N | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT tolerated (0.82); PolyPhen benign (0.003); catalogued as COSV99586467; called by muse, mutect2, varscan2
- OR10AG1 | c.446G>T p.G149V | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.119); catalogued as COSV100400205; called by muse, mutect2, varscan2
- OR11H4 | c.860T>A p.V287E | Missense Mutation (SNP) | VAF 80/120 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as COSV100197630; called by muse, mutect2, varscan2
- OR1C1 | c.745G>A p.V249M | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.82); catalogued as COSV101376286; called by muse, mutect2, varscan2
- OR2L2 | c.751T>A p.Y251N | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.337); catalogued as COSV100824340, COSV63550489; called by muse, mutect2, varscan2
- OR2T34 | c.695G>T p.R232M | Missense Mutation (SNP) | VAF 44/168 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV60899992, COSV60900064; called by muse, mutect2, varscan2
- OR7D2 | c.335C>T p.T112M | Missense Mutation (SNP) | VAF 17/166 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.511); catalogued as rs533696058, COSV60141757; called by muse, mutect2, varscan2
- OR7D4 | c.656C>A p.S219Y | Missense Mutation (SNP) | VAF 36/64 reads (56%) | SIFT tolerated (0.06); PolyPhen benign (0.038); catalogued as COSV100432874; called by muse, mutect2, varscan2
- PCARE | c.1688A>G p.D563G | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.054); catalogued as COSV100527891; called by muse, mutect2, varscan2
- PCDH11X | c.3862G>T p.G1288W | Missense Mutation (SNP) | VAF 151/319 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.87); catalogued as COSV53485723; called by muse, mutect2, varscan2
- PDCL3 | c.132G>T p.V44= | Splice Region (SNP) | VAF 10/56 reads (18%) | catalogued as COSV51810574, COSV99959718; called by muse, mutect2, varscan2
- PDS5A | c.3134A>G p.N1045S | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.954); catalogued as rs578211023, COSV100337567; called by muse, mutect2, varscan2
- PECR | c.583C>T p.R195W | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774604887, COSV99526988; called by muse, mutect2, varscan2
- PER1 | c.2942C>T p.P981L | Missense Mutation (SNP) | VAF 23/31 reads (74%) | SIFT deleterious (0); PolyPhen benign (0.092); catalogued as COSV57917024; called by muse, mutect2, varscan2
- PHC3 | c.167G>A p.R56Q (on ENST00000494943 / NM_001308116.2; = p.R68Q on NM_024947.4) | Missense Mutation (SNP) | VAF 36/152 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1200895624, COSV71923508; called by muse, mutect2, varscan2
- PHF8 | c.799G>A p.V267I (on ENST00000357988 / NM_001184896.1; = p.V231I on NM_015107.3) | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs377084478, COSV100154885; called by muse, mutect2, varscan2
- PHKG2 | c.1058G>A p.C353Y | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.047); catalogued as COSV100079833; called by muse, mutect2, varscan2
- PIK3R3 | c.34G>A p.D12N | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as COSV99422940; called by muse, mutect2, varscan2
- PLEKHO1 | c.202G>T p.E68* | Nonsense Mutation (SNP) | VAF 637/775 reads (82%) | catalogued as COSV50310260, COSV99215418; called by muse, mutect2, varscan2
- PLP1 | c.428G>T p.G143V | Missense Mutation (SNP) | VAF 39/213 reads (18%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as COSV100393553; called by muse, mutect2, varscan2
- PPFIBP1 | c.3005C>T p.A1002V (on ENST00000318304 / NM_177444.3; = p.A996V on NM_003622.4) | Missense Mutation (SNP) | VAF 40/84 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.04); catalogued as COSV99945456; called by muse, mutect2, varscan2
- PRDM14 | c.558C>A p.N186K | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as COSV99400533; called by muse, mutect2, varscan2
- PTPN14 | c.3371G>T p.G1124V | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100872945; called by muse, mutect2, varscan2
- PTPRC | c.2959C>A p.L987I | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.773); catalogued as COSV100723211; called by muse, mutect2, varscan2
- R3HDM1 | c.2218G>A p.G740S | Missense Mutation (SNP) | VAF 63/137 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.14); catalogued as COSV99926829; called by muse, mutect2, varscan2
- RAB9B | c.14C>T p.S5F | Missense Mutation (SNP) | VAF 32/175 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV99686142; called by muse, mutect2, varscan2
- RBM43 | c.442G>T p.G148* | Nonsense Mutation (SNP) | VAF 48/157 reads (31%) | catalogued as COSV100508670; called by muse, mutect2, varscan2
- REST | c.2894C>T p.T965I | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV100471354; called by muse, mutect2, varscan2
- RET | c.1096G>T p.E366* | Nonsense Mutation (SNP) | VAF 10/29 reads (34%) | catalogued as COSV100393599, COSV100393914; called by muse, mutect2, varscan2
- RIC8A | c.228C>A p.D76E | Missense Mutation (SNP) | VAF 39/73 reads (53%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.958); catalogued as COSV100254928; called by muse, mutect2, varscan2
- RICTOR | c.617G>A p.G206D | Missense Mutation (SNP) | VAF 27/229 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.502); catalogued as COSV99705766; called by muse, mutect2, varscan2
- ROBO2 | c.175A>G p.T59A | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT tolerated (0.43); PolyPhen benign (0.014); catalogued as rs758055441, COSV100170021; called by muse, mutect2, varscan2
- SAFB | c.1946G>A p.R649Q | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.86); catalogued as COSV52650318; called by muse, mutect2, varscan2
- SHROOM4 | c.4288C>A p.R1430S | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.557); catalogued as COSV99174705; called by muse, mutect2, varscan2
- SIDT1 | c.2227C>T p.P743S | Missense Mutation (SNP) | VAF 81/277 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.378); catalogued as COSV99334733; called by muse, mutect2, varscan2
- SLC22A11 | c.1634T>C p.V545A | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV100102715; called by muse, mutect2, varscan2
- SLC44A5 | c.1204G>T p.V402L | Missense Mutation (SNP) | VAF 56/117 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.081); catalogued as COSV100902685; called by muse, mutect2, varscan2
- SLITRK1 | c.1264C>G p.L422V | Missense Mutation (SNP) | VAF 39/149 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1270893720, CD054423, COSV100999989; called by muse, mutect2, varscan2
- SNAP47 | c.314C>G p.A105G | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.225); catalogued as COSV100248497; called by muse, mutect2, varscan2
- SORCS1 | c.296T>C p.M99T | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as rs374412857; called by muse, mutect2, varscan2
- SPATA31D1 | c.4124G>A p.W1375* | Nonsense Mutation (SNP) | VAF 4/32 reads (13%) | catalogued as COSV100783061; called by muse, mutect2
- SPATA31D1 | c.4334C>A p.P1445Q | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.55); PolyPhen benign (0.079); catalogued as COSV100783062; called by muse, mutect2, varscan2
- SYNE1 | c.13099A>T p.I4367F (on ENST00000367255 / NM_182961.4; = p.I4296F on NM_033071.3) | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV99579190; called by muse, mutect2, varscan2
- TEAD2 | c.1084C>G p.R362G | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV100115165; called by muse, mutect2, varscan2
- TENM4 | c.2926C>T p.R976W | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53619075; called by muse, mutect2, varscan2
- TET2 | c.1775A>C p.Y592S | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.03); catalogued as COSV99484881; called by muse, mutect2, varscan2
- TIA1 | c.425C>T p.A142V (on ENST00000433529 / NM_001351511.1; = p.A131V on NM_022037.4 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.04); catalogued as rs372738231; called by muse, mutect2, varscan2
- TLR6 | c.1769C>G p.T590S | Missense Mutation (SNP) | VAF 55/94 reads (59%) | SIFT deleterious (0.02); PolyPhen benign (0.024); catalogued as COSV101126312; called by muse, mutect2, varscan2
- TM2D1 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as COSV99624081; called by muse, mutect2, varscan2
- TMC2 | c.1964G>A p.G655D | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as COSV100727988; called by muse, mutect2, varscan2
- TMED3 | c.626G>T p.R209L | Missense Mutation (SNP) | VAF 43/88 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs145001674; called by muse, mutect2, varscan2
- TMEM135 | c.238G>T p.A80S | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as COSV100450233; called by muse, mutect2, varscan2
- TNPO3 | c.2680C>A p.Q894K | Missense Mutation (SNP) | VAF 25/40 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99603496; called by muse, mutect2, varscan2
- TNRC6A | c.2042G>C p.R681P | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.076); catalogued as COSV100170492, COSV100170601; called by muse, mutect2, varscan2
- TRPM4 | c.1436A>G p.Q479R | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as COSV99420966; called by muse, mutect2, varscan2
- TTN | c.85670A>G p.H28557R (on ENST00000591111; = p.H21133R on NM_003319.4) | Missense Mutation (SNP) | VAF 14/71 reads (20%) | PolyPhen benign (0.033); catalogued as rs1479999162, COSV100630521; called by muse, mutect2, varscan2
- TTN | c.72871G>T p.D24291Y (on ENST00000591111; = p.D16867Y on NM_003319.4) | Missense Mutation (SNP) | VAF 7/29 reads (24%) | PolyPhen probably damaging (0.999); catalogued as COSV100630525; called by muse, mutect2, varscan2
- TTN | c.27577T>A p.S9193T (on ENST00000591111; = p.S8266T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/73 reads (22%) | PolyPhen benign (0.005); catalogued as COSV100630526; called by muse, mutect2, varscan2
- UHRF2 | c.2343G>C p.M781I | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.074); catalogued as COSV99437223; called by muse, mutect2, varscan2
- UXS1 | c.370G>T p.G124C | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99308781; called by muse, mutect2, varscan2
- VAX1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 24/37 reads (65%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.678); catalogued as COSV99524432, COSV99524462; called by muse, mutect2, varscan2
- VPS13B | c.7228G>A p.D2410N | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs1347208371, COSV100663732, COSV62153951; called by muse, mutect2
- YARS1 | c.61G>T p.V21F | Missense Mutation (SNP) | VAF 163/438 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.378); catalogued as COSV100993514; called by muse, mutect2, varscan2
- ZBTB20 | c.1618G>T p.V540L (on ENST00000474710 / NM_001164342.2; = p.V467L on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.069); catalogued as COSV100615299; called by muse, mutect2, varscan2
- ZNF174 | c.553G>C p.D185H | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.326); catalogued as rs1366607933, COSV99237738; called by muse, mutect2, varscan2
- ZNF804A | c.3462G>T p.R1154S | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV56443990; called by muse, mutect2, varscan2
- ZNF831 | c.4688A>C p.E1563A | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as COSV100926272; called by muse, mutect2, varscan2
- ACTR3B | c.259del p.D87Ifs*25 | Frame Shift Del (DEL) | VAF 16/68 reads (24%) | called by mutect2, pindel, varscan2
- CST4 | c.196_216del p.R66_R72del | In Frame Del (DEL) | VAF 8/57 reads (14%) | called by mutect2, pindel
- FNBP4 | c.815T>C p.V272A | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2
- HUWE1 | c.13107_*3del | Nonstop Mutation (DEL) | VAF 8/30 reads (27%) | called by mutect2, pindel
- MYO19 | c.628A>G p.M210V | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- NAA10 | c.577del p.A193Pfs*58 | Frame Shift Del (DEL) | VAF 46/100 reads (46%) | called by mutect2, pindel, varscan2
- SDCCAG8 | c.303del p.L102* | Frame Shift Del (DEL) | VAF 15/47 reads (32%) | called by mutect2, pindel, varscan2
- STAG2 | c.1701dup p.A568Cfs*20 | Frame Shift Ins (INS) | VAF 52/119 reads (44%) | called by mutect2, pindel, varscan2
- TIMM17B | c.211G>A p.G71S | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- TRAV12-2 | c.293G>C p.R98T | Missense Mutation (SNP) | VAF 42/138 reads (30%) | SIFT tolerated (0.94); PolyPhen benign (0.155); called by muse, varscan2
- ZNF8 | c.1268dup p.P424Afs*3 | Frame Shift Ins (INS) | VAF 17/83 reads (20%) | called by mutect2, pindel, varscan2
- ABCC4 | c.900C>G p.T300= | Silent (SNP) | VAF 7/148 reads (5%) | catalogued as COSV100972806; called by muse, mutect2
- ADAMTSL1 | c.2235C>A p.G745= | Silent (SNP) | VAF 24/42 reads (57%) | catalogued as rs189207113, COSV101002048; called by muse, mutect2, varscan2
- AGBL2 | c.1221C>T p.L407= | Silent (SNP) | VAF 36/107 reads (34%) | catalogued as COSV100102138; called by muse, mutect2, varscan2
- AGRN | c.4983G>A p.K1661= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as COSV101039096; called by muse, mutect2, varscan2
- CACNG7 | c.375G>A p.P125= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as rs766519700, COSV55816649; called by muse, mutect2, varscan2
- CAT | c.465C>T p.I155= | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as COSV99573476; called by muse, mutect2, varscan2
- CATSPERB | c.231C>T p.F77= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as COSV99831790; called by muse, mutect2, varscan2
- DAGLA | c.375C>T p.S125= | Silent (SNP) | VAF 43/81 reads (53%) | catalogued as COSV99944735; called by muse, mutect2, varscan2
- DCDC1 | c.3804T>C p.N1268= (on ENST00000597505 / NM_001367979.1; = p.N375= on NM_020869.3) | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as COSV100337925; called by muse, mutect2, varscan2
- DEPDC1 | c.1902C>T p.P634= (on ENST00000456315 / NM_001114120.3; = p.P350= on NM_017779.6) | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as COSV100920486; called by muse, mutect2, varscan2
- DLX3 | c.228C>T p.G76= | Silent (SNP) | VAF 28/83 reads (34%) | catalogued as COSV101460579; called by muse, mutect2, varscan2
- DSCAML1 | c.1299C>T p.I433= (on ENST00000321322; = p.I373= on NM_020693.4) | Silent (SNP) | VAF 31/87 reads (36%) | catalogued as COSV100357281; called by muse, mutect2, varscan2
- ETNK2 | c.732G>A p.V244= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV100916626; called by muse, mutect2, varscan2
- FAT2 | c.1635G>A p.E545= | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as COSV99944148; called by muse, mutect2, varscan2
- FIG4 | c.2334C>T p.P778= | Silent (SNP) | VAF 23/47 reads (49%) | catalogued as rs1183428109, COSV100019914, COSV100020039; called by muse, mutect2, varscan2
- FMNL3 | c.930C>T p.F310= | Silent (SNP) | VAF 8/158 reads (5%) | catalogued as COSV53305778, COSV99527005; called by muse, mutect2
- GCAT | c.1089G>T p.A363= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as COSV99959940; called by muse, mutect2, varscan2
- GPC5 | c.1047A>T p.V349= | Silent (SNP) | VAF 585/620 reads (94%) | catalogued as COSV100996083; called by muse, mutect2, varscan2
- GRB10 | c.417C>T p.P139= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as COSV60007692; called by muse, mutect2
- IL9R | c.951T>C p.S317= | Silent (SNP) | VAF 22/105 reads (21%) | catalogued as COSV99730236; called by muse, mutect2, varscan2
- ITGA7 | c.564C>T p.P188= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as rs763955304, COSV99160273; called by muse, mutect2, varscan2
- KCNK1 | c.474G>T p.V158= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV100785787, COSV100785817; called by muse, mutect2, varscan2
- KIAA1210 | c.4002C>A p.S1334= | Silent (SNP) | VAF 86/397 reads (22%) | catalogued as COSV101274258, COSV101274401; called by muse, mutect2, varscan2
- KLHL34 | c.567G>A p.A189= | Silent (SNP) | VAF 10/19 reads (53%) | catalogued as rs1010801012, COSV65280438; called by muse, mutect2, varscan2
- KLRG1 | c.54C>T p.A18= | Silent (SNP) | VAF 48/104 reads (46%) | catalogued as COSV99868624; called by muse, mutect2, varscan2
- KRT84 | c.393C>T p.V131= | Silent (SNP) | VAF 33/135 reads (24%) | catalogued as COSV99230986; called by muse, mutect2, varscan2
- KRTAP5-2 | c.420C>A p.P140= | Silent (SNP) | VAF 114/234 reads (49%) | catalogued as COSV101295128; called by muse, mutect2, varscan2
- LILRB4 | c.570G>T p.G190= | Silent (SNP) | VAF 21/90 reads (23%) | catalogued as COSV99553528; called by muse, mutect2, varscan2
- LTBP4 | c.4773G>A p.A1591= (on ENST00000308370 / NM_001042544.1; = p.A1554= on NM_003573.2) | Silent (SNP) | VAF 40/64 reads (63%) | catalogued as rs371783184; called by muse, mutect2, varscan2
- MCRS1 | c.396G>T p.L132= | Silent (SNP) | VAF 46/86 reads (53%) | catalogued as COSV100657435; called by muse, mutect2, varscan2
- MKRN3 | c.258G>T p.P86= | Silent (SNP) | VAF 22/67 reads (33%) | catalogued as COSV100090600, COSV58809496; called by muse, mutect2, varscan2
- MOS | c.732C>A p.T244= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as rs56148175; called by muse, mutect2, varscan2
- MUC16 | c.8313G>T p.T2771= | Silent (SNP) | VAF 22/47 reads (47%) | catalogued as COSV101201762, COSV67487330; called by muse, mutect2, varscan2
- MUC2 | c.1992C>T p.P664= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as rs373504635; called by muse, mutect2, varscan2
- NLRP2 | c.423C>A p.V141= | Silent (SNP) | VAF 13/81 reads (16%) | catalogued as COSV99672671; called by muse, mutect2, varscan2
- NOM1 | c.1101T>G p.G367= | Silent (SNP) | VAF 17/40 reads (43%) | catalogued as COSV99316071; called by muse, mutect2, varscan2
- OR5L1 | c.93C>T p.F31= | Silent (SNP) | VAF 151/300 reads (50%) | catalogued as rs1247996381, COSV100450285; called by muse, mutect2, varscan2
- OR8I2 | c.39C>T p.I13= | Silent (SNP) | VAF 79/182 reads (43%) | catalogued as COSV100136267; called by muse, mutect2, varscan2
- PARVB | c.1023G>T p.V341= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as COSV100115239; called by muse, mutect2, varscan2
- PCDH19 | c.891G>T p.L297= | Silent (SNP) | VAF 37/84 reads (44%) | catalogued as COSV99720678; called by muse, mutect2, varscan2
- PLXNC1 | c.1734C>T p.F578= | Silent (SNP) | VAF 26/124 reads (21%) | catalogued as rs760549221, COSV51577049; called by muse, mutect2, varscan2
- PRDM4 | c.2193C>A p.V731= | Silent (SNP) | VAF 41/173 reads (24%) | catalogued as COSV99946739; called by muse, mutect2, varscan2
- PRELP | c.597C>A p.L199= | Silent (SNP) | VAF 24/101 reads (24%) | catalogued as COSV100557963; called by muse, mutect2, varscan2
- PREX1 | c.2640C>T p.F880= | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as rs373448744; called by muse, mutect2, varscan2
- RAB30 | c.597T>C p.C199= | Silent (SNP) | VAF 26/99 reads (26%) | catalogued as rs145192420; called by muse, mutect2, varscan2
- RALBP1 | c.1656G>A p.L552= | Silent (SNP) | VAF 22/78 reads (28%) | catalogued as COSV50035476, COSV99192038; called by muse, mutect2, varscan2
- SHROOM2 | c.807G>T p.P269= | Silent (SNP) | VAF 13/15 reads (87%) | catalogued as rs375430450, COSV101099061; called by muse, mutect2, varscan2
- SLC1A6 | c.918G>T p.L306= | Silent (SNP) | VAF 35/87 reads (40%) | catalogued as COSV99694225; called by muse, mutect2, varscan2
- SLC5A6 | c.1521G>T p.L507= | Silent (SNP) | VAF 17/37 reads (46%) | catalogued as COSV100143604; called by muse, mutect2, varscan2
- TGFBRAP1 | c.1191C>T p.F397= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as COSV99305549; called by muse, mutect2, varscan2
- TGFBRAP1 | c.1071A>G p.G357= | Silent (SNP) | VAF 32/114 reads (28%) | catalogued as COSV99305550; called by muse, mutect2, varscan2
- TMEM74B | c.267G>A p.G89= | Silent (SNP) | VAF 13/62 reads (21%) | catalogued as rs1350491727, COSV101121996; called by muse, mutect2, varscan2
- TRIML1 | c.1341C>A p.P447= | Silent (SNP) | VAF 28/72 reads (39%) | catalogued as COSV100206337, COSV60194448; called by muse, mutect2, varscan2
- TSHZ3 | c.2922C>T p.P974= | Silent (SNP) | VAF 12/70 reads (17%) | catalogued as rs755360689, COSV53680146, COSV99552795; called by muse, mutect2, varscan2
- TUBB1 | c.819C>T p.L273= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as COSV99414093; called by muse, mutect2, varscan2
- TUFM | c.429C>A p.G143= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as COSV100493192; called by muse, mutect2, varscan2
- WSCD2 | c.123C>T p.G41= | Silent (SNP) | VAF 34/146 reads (23%) | catalogued as COSV99775280; called by muse, mutect2, varscan2
- XIRP2 | c.33T>C p.F11= (on ENST00000628543; = p.F186= on NM_152381.6) | Silent (SNP) | VAF 31/59 reads (53%) | catalogued as COSV99747577; called by muse, mutect2, varscan2
- ZNF221 | c.1422T>A p.G474= | Silent (SNP) | VAF 15/72 reads (21%) | catalogued as rs1335811127, COSV52108727, COSV99240964; called by muse, mutect2, varscan2
- ZNF761 | c.444G>T p.L148= | Silent (SNP) | VAF 43/107 reads (40%) | catalogued as rs757125235, COSV100483488; called by muse, mutect2, varscan2
- MASP1 | c.1303+4971G>T | Intron (SNP) | VAF 88/299 reads (29%) | catalogued as rs147966392, COSV56228175, COSV99962853; called by muse, mutect2, varscan2
- SNORD115-14 | n.38G>T | RNA (SNP) | VAF 93/235 reads (40%) | called by muse, mutect2, varscan2
- XIST | n.7698C>G | RNA (SNP) | VAF 65/123 reads (53%) | called by muse, mutect2, varscan2
